Gene-level copy-number profile of tumor specimen ALCH-B38E-TTR1-A from ALCHEMIST case ALCH-B38E, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.6 years (24,324 days).
Specimen ALCH-B38E-TTR1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6b165902-d967-47e9-96de-637866143b03.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B38E-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/c21a2f2c-1653-4e00-a0f8-db10967aa87f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 39; copy number 1: 6,632; copy number 2: 50,342; copy number 3: 1,373; copy number 4: 7; copy number 8: 1.

Homozygous deletions (total copy number 0; autosomes only): 39 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,319,625–89,600,680, 3 genes: IGKV1-39, IGKV2-40, 5S_rRNA.
- chr2:89,906,757–89,937,679, 5 genes: IGKV3D-34, IGKV1D-33, IGKV1D-32, IGKV3D-31, IGKV2D-30.
- chr7:43,940,895–44,019,175, 6 genes (within-gene range 0–2): POLR2J4, AC004951.4, AC004951.3, AC004951.2, SPDYE1, AC004951.1.
- chr7:44,013,562–44,019,170, 1 gene (within-gene range 0–2): POLR2J4.
- chr7:62,275,361–62,275,678, 1 gene: AC128676.1.
- chr7:128,912,732–128,914,063, 1 gene: AC025594.1.
- chr8:43,672,823–43,674,591, 2 genes: AC139365.2, AC139365.1.
- chr9:40,755,407–40,883,763, 4 genes: AL353626.3, RNU6-156P, AL353626.1, AL353626.2.
- chr9:65,189,995–65,285,209, 5 genes: BMS1P12, AL512605.1, AL512605.2, IGKV1OR9-1, FOXD4L5.
- chr11:48,880,111–48,908,946, 4 genes: AC027369.6, AC027369.3, AC027369.4, AC027369.5.
- chr11:50,409,042–50,422,316, 1 gene: AC024405.1.
- chr12:118,063,593–118,136,026, 2 genes (within-gene range 0–2): VSIG10, AC131238.1.
- chr19:27,638,483–27,794,005, 4 genes (within-gene range 0–2): ERVK-28, AC112702.1, LINC00662, AC006504.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,070,967–1,074,306, 1 gene, copy number 8: RNF223.

Autosomal genes at a single copy (total copy number 1): 6,574. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
